Surgical pathology report (de-identified scan), TCGA case TCGA-EI-6506, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-EI-6506-01A (Primary Tumor).

Examination: Histopathological examination

Material: 1. Partial organ resection – segment of the large intestine

TCGA – EI – 6506

Clinical diagnosis: 1/ Ca. recti.

SPECIMEN – distal segment of the sigmoid colon and proximal segment of the rectum with the tumour. Proximal end marked with a thread. 2/ Ca. recti.

SPECIMEN – rings of the sigmoid colon-rectum anastomosis.

Examination performed on:

Macroscopic description:

1. 13 cm length of the large intestine with a segment of the mesenterium sized 14 x 6 x 2.5 cm. Ulcerous, flat-elevated, cauliflower-shaped tumour sized 4.5 x 3.5 cm found in the mucosa. The lesion surrounds 90% of the intestine circumference and narrows its cross section, located 5.5 cm from one of the incision lines and 4.5 cm from the opposite one. Lesion invading macroscopically the periintestinal tissue.

Minimum side margin is 2.3 cm.

2. Two surgical specimens sized 2.5 x 1.8 x 1.2 cm and 2.5 x 2.0 x 1.3 cm.

Microscopic description:

1. Adenocarcinoma tubulare (G2).

Infiltratio carcinomatosa tunicae muscularis propriae et telae adiposae pericolicae.

Incision lines free of neoplastic lesions.

Lymphonodulitis reactiva No XIX

2. Anastomosis rings free of cancer invasion.

Examination result/Histopathological diagnosis:

Adenocarcinoma tubulare coli. Tubullar adenocarcinoma of the colon (G2, Dukes B, Astler-Coller B2, pT3, pN0).

Source: NCI Genomic Data Commons file 8ffbbc0c-32d0-4dd0-938a-05433bdc786e (TCGA-EI-6506.D313E6F8-47FB-4E77-A726-2537AEEB9489.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).